Somatic mutation profile of tumor specimen TCGA-CH-5745-01A (aliquot TCGA-CH-5745-01A-11D-1576-08) from TCGA case TCGA-CH-5745, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.0 years (24,837 days).
Specimen TCGA-CH-5745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 008ae69a-7351-461d-a827-2c34e0c3b5ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5745-10A (Blood Derived Normal), aliquot TCGA-CH-5745-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e34a095a-a931-4b29-af4c-6ed9f19f3d1c

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BANF2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs375278663, COSV55724927; called by muse, mutect2, varscan2
- CCNA1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV55221957; called by muse, mutect2, varscan2
- CHRD | c.2309A>G p.D770G | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV52608760; called by muse, mutect2, varscan2
- EMID1 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.603); catalogued as COSV61829620; called by mutect2, varscan2
- GOLGA5 | c.241A>C p.T81P | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as COSV50833320; called by muse, mutect2
- GRM5 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761709134, COSV59604165; called by muse, mutect2, varscan2
- HBG2 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57963768; called by muse, mutect2, varscan2
- HMCN1 | c.12533A>G p.Y4178C | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV54904974; called by muse, mutect2
- INO80 | c.523A>C p.S175R | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs762338137, COSV62738630; called by muse, mutect2, varscan2
- LRIG1 | c.736A>C p.N246H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as COSV56240985; called by muse, mutect2, varscan2
- NCKAP5 | c.4382C>T p.A1461V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58447066; called by muse, mutect2, varscan2
- OR5D16 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 81/581 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1224663701, COSV101004091, COSV65721624; called by muse, mutect2, varscan2
- PANK1 | c.1207T>A p.C403S (on ENST00000307534 / NM_148977.2; = p.C178S on NM_138316.4) | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.144); catalogued as COSV56808449; called by muse, mutect2, varscan2
- PTPRO | c.2899C>T p.R967C (on ENST00000281171 / NM_030667.3; = p.R939C on NM_002848.4) | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257571508, COSV55511710; called by muse, mutect2, varscan2
- TDO2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.906); catalogued as rs751379546, COSV101539792, COSV72483902; called by muse, mutect2, varscan2
- TSSK2 | c.638C>A p.S213Y | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV52817171; called by muse, mutect2, varscan2
- WNK4 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs760831283, COSV53820905; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as COSV54296575; called by muse, mutect2, varscan2
- NKX3-1 | c.304del p.Y102Ifs*35 | Frame Shift Del (DEL) | VAF 47/217 reads (22%) | called by mutect2, pindel, varscan2
- FYTTD1 | c.450G>A p.Q150= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV54083977, COSV99611386; called by muse, varscan2
- PLEC | c.9387C>A p.I3129= (on ENST00000322810 / NM_201380.4; = p.I3019= on NM_000445.5) | Silent (SNP) | VAF 3/55 reads (5%) | catalogued as COSV59643293; called by muse, mutect2
- PLEKHS1 | c.291C>T p.V97= (on ENST00000369310 / NM_182601.1; = p.V103= on NM_024889.5) | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV63055423; called by muse, mutect2, varscan2
- TXNDC11 | c.1638C>T p.F546= (on ENST00000356957 / NM_001303447.2; = p.F519= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 109/334 reads (33%) | catalogued as COSV51599641; called by muse, mutect2, varscan2
